Somatic mutation profile of tumor specimen TCGA-YZ-A980-01A (aliquot TCGA-YZ-A980-01A-11D-A39W-08) from TCGA case TCGA-YZ-A980, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.9 years (27,716 days).
Specimen TCGA-YZ-A980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea1a2f17-d6bf-41a5-aa16-a2301f7d55cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YZ-A980-10A (Blood Derived Normal), aliquot TCGA-YZ-A980-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/999a4121-236f-458f-bd16-4cca854805f3

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 5, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DRG1 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100513780; called by muse, mutect2, varscan2
- KCNH5 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs899330305, COSV59760144, COSV99063064; called by muse, mutect2, varscan2
- PSAP | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs374177795; called by muse, mutect2, varscan2
- BAP1 | c.1013del p.P338Lfs*24 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- CCAR2 | c.2175dup p.E726Rfs*86 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- EIF1B | c.246dup p.I83Yfs*6 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- RNF167 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- EIF2B5 | c.774C>T p.S258= (on ENST00000647909; = p.S250= on NM_003907.3) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56606336; called by muse, mutect2, varscan2
- FSHR | c.141T>C p.N47= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- PPARD | c.1275C>G p.T425= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs764302707; called by muse, mutect2
- STK4 | c.1287G>A p.Q429= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- TRIML1 | c.1206G>A p.E402= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs376744139; called by muse, mutect2, varscan2
